Gene-level copy-number profile of tumor specimen TCGA-AG-3578-01A from TCGA case TCGA-AG-3578, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.3 years (27,851 days).
Specimen TCGA-AG-3578-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.4d3a07db-3239-406b-a153-97afbaacf147.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3578-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/adafbfc3-327a-4c18-8aa9-3b3cf270c4ca

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 14; copy number 2: 11,549; copy number 3: 11,240; copy number 4: 32,321; copy number 5: 2,604; copy number 6: 430; copy number 7: 81; copy number 8: 15; copy number 9: 1,564.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AG-3578-01): tumor purity 0.77, ploidy 3.6, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,564 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:65,020,038–66,572,546, 29 genes, copy number 9: AC092354.2, AC092354.1, Y_RNA, ADAMTS6, AC008868.1, RPEP1, AC025186.1, AC025176.1, CENPK, PPWD1, TRIM23, RNU6-540P, TRAPPC13, SHLD3, SGTB, NLN, AC008958.1, AC010359.2, ERBIN, AC010359.1, AC010359.3, AC025442.2, SREK1, AC025442.1, LINC02065, AC092353.1, AC092353.2, LINC02229, PPIAP78.
- chr5:66,622,868–66,623,177, 1 gene, copy number 9: AC092349.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
